Gene-level copy-number profile of tumor specimen ALCH-B0CI-TTP1-A from ALCHEMIST case ALCH-B0CI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.6 years (23,958 days).
Specimen ALCH-B0CI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5a5c2e47-6766-43ac-8f0b-53ce8a54b598.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0CI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/82dcd5c2-990c-4247-98c7-32831e8bc3e8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,978; copy number 2: 55,603; copy number 3: 328; copy number 4: 4; copy number 5: 1; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:43,140,523–43,141,092, 1 gene, copy number 5: FRGCA.
- chr22:18,636,445–18,719,341, 3 genes, copy number 6: CA15P2, PPP1R26P2, PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 137. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
